Somatic mutation profile of tumor specimen TCGA-G2-A3IB-01A (aliquot TCGA-G2-A3IB-01A-11D-A20D-08) from TCGA case TCGA-G2-A3IB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.1 years (24,149 days).
Specimen TCGA-G2-A3IB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bdeb2b7-3e5a-4a89-b8ca-38052b9a02bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A3IB-10A (Blood Derived Normal), aliquot TCGA-G2-A3IB-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53093404-76e0-4e2f-9247-0be2fa6fa76c

The open-access MAF lists 101 somatic variants for this specimen: 83 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 15, Nonsense Mutation 6, Intron 2, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 19/29 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 42/83 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV59392593; called by muse, mutect2, varscan2
- ADAMTS12 | c.2439G>T p.Q813H | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV61280257; called by muse, mutect2, varscan2
- AFF2 | c.3274A>C p.K1092Q | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54008185; called by muse, mutect2, varscan2
- AL592490.1 | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV69427913; called by muse, mutect2, varscan2
- BTAF1 | c.2860A>G p.T954A | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1275408503, COSV56439550; called by muse, mutect2, varscan2
- C1QTNF9 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59658227; called by muse, mutect2, varscan2
- C2orf42 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV52452922; called by muse, varscan2
- C2orf42 | c.1283G>C p.G428A | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52452936; called by muse, varscan2
- CDKN1A | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 35/113 reads (31%) | catalogued as rs1407742055, COSV55187604; called by muse, mutect2, varscan2
- CDYL2 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200689533, COSV73654222; called by muse, mutect2, varscan2
- CFAP20DC | c.1330G>A p.G444S (on ENST00000482387 / NM_001351530.2; = p.G319S on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV55927685; called by muse, mutect2, varscan2
- CHRM3 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.3); catalogued as COSV55104926; called by muse, mutect2, varscan2
- CHRNB4 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV55718439; called by muse, mutect2, varscan2
- COCH | c.637C>T p.R213* (on ENST00000216361 / NM_001347720.1; = p.R148* on NM_004086.3) | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs755252656, COSV53551744; ClinVar: uncertain significance; called by muse, varscan2
- COL11A1 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62198077; called by muse, mutect2, varscan2
- CYP4A22 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.211); catalogued as COSV53742489; called by muse, mutect2, varscan2
- DCLK2 | c.494G>T p.W165L | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV56212364; called by muse, mutect2, varscan2
- DIO3 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV63774637; called by muse, mutect2
- DMXL2 | c.9090C>A p.N3030K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51856427; called by muse, mutect2, varscan2
- EEF1B2 | c.269G>C p.S90T | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV51913875; called by muse, mutect2, varscan2
- ELAVL4 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63919186; called by muse, mutect2, varscan2
- EME1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 46/110 reads (42%) | catalogued as COSV56812828; called by muse, mutect2, varscan2
- FAM71D | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV100315295; called by muse, mutect2
- GP2 | c.1585C>A p.L529M (on ENST00000381362 / NM_001007240.3; = p.L526M on NM_001502.4) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.77); catalogued as COSV56896712; called by muse, mutect2, varscan2
- GPRIN2 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV65402695; called by muse, mutect2, varscan2
- GRIK5 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.412); catalogued as COSV53486086; called by muse, mutect2, varscan2
- GUCY2F | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV54308825; called by muse, mutect2, varscan2
- HIRA | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224024599, COSV54274191; called by muse, mutect2, varscan2
- HRG | c.436G>T p.D146Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV51648320; called by muse, mutect2, varscan2
- HTR1D | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58447323, COSV58449474; called by muse, mutect2, varscan2
- ISX | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58088377; called by muse, mutect2, varscan2
- KAT6B | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54754861; called by muse, mutect2, varscan2
- KIFAP3 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.197); catalogued as COSV63037356; called by muse, mutect2, varscan2
- KMT2D | c.902del p.F301Sfs*3 | Frame Shift Del (DEL) | VAF 77/198 reads (39%) | catalogued as COSV56466138; called by mutect2, pindel, varscan2
- LHX5 | c.354C>A p.D118E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV55664271; called by muse, mutect2, varscan2
- MAPK10 | c.608A>C p.K203T (on ENST00000359221 / NM_001351625.2; = p.K241T on NM_002753.5) | Missense Mutation (SNP) | VAF 52/65 reads (80%) | SIFT tolerated (0.58); PolyPhen benign (0.049); catalogued as COSV60394410; called by muse, mutect2, varscan2
- MFSD9 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as rs867046037, COSV51495754; called by muse, mutect2, varscan2
- MISP | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs112598403, COSV53120135; called by muse, mutect2, varscan2
- MPDZ | c.5093G>C p.R1698T | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59924655; called by muse, mutect2, varscan2
- MUC16 | c.5948C>T p.S1983F | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67494870; called by muse, mutect2, varscan2
- NLRP11 | c.2885C>A p.T962N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64088849; called by muse, mutect2, varscan2
- NLRP6 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV56462004; called by muse, mutect2, varscan2
- NMBR | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV57803424; called by muse, mutect2, varscan2
- NTRK2 | c.1299C>A p.V433= | Splice Region (SNP) | VAF 35/81 reads (43%) | catalogued as COSV52882864; called by muse, mutect2, varscan2
- NUP98 | c.2177C>G p.S726C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV61432745, COSV61438581; called by muse, mutect2, varscan2
- OR1Q1 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112809062, COSV52919210; called by muse, mutect2, varscan2
- OR4A5 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV60524725; called by muse, mutect2, varscan2
- PCNT | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780769402, COSV64033147; called by muse, mutect2, varscan2
- PIWIL3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV59995430, COSV59998257; called by muse, mutect2, varscan2
- PNLIPRP3 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1334021707, COSV65049711; called by muse, mutect2, varscan2
- PPP1R13B | c.2356G>T p.A786S | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV52456420; called by muse, mutect2, varscan2
- PRDM14 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1277239045, COSV52575391; called by muse, mutect2, varscan2
- PTCH1 | c.3855G>T p.Q1285H | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59494302; called by muse, mutect2, varscan2
- PTPN21 | c.183C>T p.V61= | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as rs1135152, COSV60852160; called by muse, mutect2, varscan2
- RP1 | c.5673G>T p.L1891F | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs139088785, CM150439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPGRIP1L | c.227A>T p.K76I | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50917764; called by muse, mutect2, varscan2
- RYR1 | c.4243G>A p.V1415M | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as COSV62111095; called by muse, mutect2, varscan2
- SBF2 | c.4594G>C p.E1532Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.348); catalogued as COSV56311700; called by muse, mutect2, varscan2
- SCN1A | c.5267G>T p.C1756F (on ENST00000303395 / NM_001202435.3; = p.C1745F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57688143; called by muse, mutect2, varscan2
- SLC24A1 | c.1665G>T p.W555C | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56054141; called by muse, mutect2, varscan2
- SLC6A19 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763527431, COSV58670345, COSV58674634; called by muse, mutect2, varscan2
- TGFBR2 | c.1275G>T p.M425I | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55460783; called by muse, mutect2, varscan2
- TOP2A | c.1433G>C p.R478T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV70733932; called by muse, mutect2, varscan2
- TOPBP1 | c.3176G>C p.G1059A | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.193); catalogued as COSV53441802; called by muse, mutect2, varscan2
- UGGT2 | c.2164G>T p.V722L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV65079603; called by muse, mutect2, varscan2
- UGT2B4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 79/100 reads (79%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); catalogued as COSV100522437, COSV59320761; called by muse, mutect2, varscan2
- USP32 | c.3536G>T p.C1179F | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56277687; called by muse, mutect2, varscan2
- VPS39 | c.2232G>A p.M744I (on ENST00000348544 / NM_001301138.2; = p.M733I on NM_015289.5) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV58793535; called by muse, mutect2, varscan2
- XIRP2 | c.6811C>A p.L2271M (on ENST00000628543; = p.L2446M on NM_152381.6) | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.293); catalogued as COSV54735150; called by muse, mutect2, varscan2
- Z83844.2 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.073); catalogued as COSV53217556; called by muse, mutect2, varscan2
- ZBTB43 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV65095262; called by muse, mutect2, varscan2
- ZFYVE1 | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1157438772, COSV59613203; called by muse, mutect2, varscan2
- ZNF638 | c.4515C>A p.S1505R | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52497086; called by muse, mutect2, varscan2
- DNAH9 | c.3706C>A p.Q1236K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPB41L4A | c.843C>A p.C281* | Nonsense Mutation (SNP) | VAF 32/41 reads (78%) | called by muse, mutect2, varscan2
- KMT2D | c.15405_15406dup p.H5136Rfs*12 | Frame Shift Ins (INS) | VAF 43/118 reads (36%) | called by mutect2, pindel, varscan2
- OR6Y1 | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 48/125 reads (38%) | called by muse, mutect2, varscan2
- PCM1 | c.5179_5180insTC p.D1727Vfs*38 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- RSPH10B2 | c.510C>A p.F170L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- SDK2 | c.3658T>C p.W1220R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL6 | c.492C>T p.F164= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV53463931; called by muse, mutect2, varscan2
- ARHGDIA | c.468C>T p.Y156= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs779427124, COSV53907805; called by muse, mutect2, varscan2
- CMYA5 | c.2856G>T p.V952= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as COSV71409556; called by muse, mutect2, varscan2
- CTNNA2 | c.639G>A p.L213= | Silent (SNP) | VAF 29/54 reads (54%) | catalogued as rs1558601143, COSV63567740; called by muse, mutect2, varscan2
- FAM91A1 | c.225C>T p.L75= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV58235815; called by muse, mutect2, varscan2
- GCFC2 | c.1620G>A p.K540= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV58083514; called by muse, mutect2
- KCNC4 | c.120C>T p.I40= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV63926695; called by muse, mutect2, varscan2
- NOVA2 | c.1332G>A p.K444= | Silent (SNP) | VAF 79/223 reads (35%) | catalogued as COSV54359976; called by muse, mutect2, varscan2
- NPC1 | c.2841C>T p.F947= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs755936884, COSV52583712; called by muse, mutect2, varscan2
- OR10Q1 | c.198C>T p.F66= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as COSV57472038; called by muse, mutect2, varscan2
- OR4C15 | c.709T>C p.L237= (on ENST00000314644; = p.L183= on NM_001001920.2) | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs754923844, COSV58955586; called by muse, mutect2, varscan2
- RPL18A | c.117C>A p.V39= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs372248330; called by muse, mutect2, varscan2
- SPAG17 | c.5143C>A p.R1715= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV100308022, COSV60468652, COSV60469688; called by muse, mutect2, varscan2
- TFCP2L1 | c.108G>T p.L36= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as rs763242950, COSV55295245; called by muse, mutect2, varscan2
- ZNF536 | c.3663G>T p.L1221= | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV62834297; called by muse, mutect2, varscan2
- CCND3 | c.199-369C>T | Intron (SNP) | VAF 89/190 reads (47%) | catalogued as rs771632649, COSV65912537; called by muse, mutect2, varscan2
- CDC42BPA | c.4791+5092C>A | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100506232; called by muse, mutect2, varscan2
- HERC2P3 | n.1467C>A | RNA (SNP) | VAF 58/303 reads (19%) | called by muse, mutect2, varscan2
